Surgical pathology report (de-identified scan), TCGA case TCGA-EQ-5647, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-EQ-5647-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Stomach

CLINICAL NOTES

PRE-OP DIAGNOSIS: Gastric cancer with bleeding.

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "stomach" is a previously unopened 13.5 x 8 x 5.5 cm distal portion of gastric tissue with a scant amount of attached adipose tissue along the lesser and greater curvatures and smooth to scabrous/focally cauterized serosa. The proximal and distal margins measure 18.5 and 5 cm in circumference respectively. A palpable mass is present in the distal portion of the specimen and the overlying serosal surface

is inked blue. On opening, there is a poorly circumscribed, 10 x 9 cm lobulated rubbery tan white-red tumor mass within the distal portion of the specimen. The lesion appears to approach the distal margin to within 1.2 cm. On sectioning, the tumor measures up to 2.8 cm in thickness, grossly extending into the muscularis to within

0.3 cm of the inked serosal surface. The remaining gastric mucosa is unremarkable tan-pink with normal rugal folds and the walls average 0.8 cm in thickness. A few rubbery tan-white to tan-pink tissues in keeping with lymph nodes measuring up to 0.7 cm in greatest dimension are recovered from the greater and lesser curvatures. Representative sections are submitted in thirteen blocks as labeled. RS-13.

BLOCK SUMMARY: 1 - Representative proximal margin; 2,3 - tumor to distal margin; 4-7 - tumor full thickness to inked serosal surface; 8 - tumor to proximal normal mucosa; 9 - random normal mucosa; 10 - three whole lymph nodes greater curvature; 11,12 - one bisected lymph node per cassette greater curvature; 13 - six whole presumptive lymph nodes lesser curvature.

[page 2 of 2]
GROSS DESCRIPTION

Please note a portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested.

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma

Histologic grade: Moderately-differentiated

Tumor size: 10 x 9 x 2.8 cm.

Primary tumor (pT4): carcinoma is present at the serosal surface
in several areas.

Proximal margin: Negative

Distal margin: Involved by carcinoma

Radial margin: Carcinoma extends to the serosal surface

Vascular invasion: Present

Regional lymph nodes (pN): Metastatic carcinoma in eight of ten
lymph nodes (8/10), with additional tumor deposit within the
serosal
adipose tissue.

5

DIAGNOSIS

Stomach, gastrectomy:

Adenocarcinoma, moderately-differentiated, at the distal margin
of resection and the serosal surface.
Eight of ten lymph nodes with metastatic carcinoma (8/10).

--- End Of Report ---

Source: NCI Genomic Data Commons file 6c940033-af5d-44d5-afca-7c032f7b7d05 (TCGA-EQ-5647.D455B2B8-30F2-49C7-8A1A-C624AD2FA3CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).